Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A119, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A119-01A (Primary Tumor).

[page 1 of 4]
105-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site: liver C22-0 1/24/11 *lu*

Patient Key:
Surgical date:

[TISSUE DESCRIPTION:

1 A2 B1 C1 D1 E1 E2 F1 F2 F3 F4 F5 F6 F7
gallbladder (8.0 x 3.5 x 2.8 cm), peritoneal biopsies (No.1, 3 mm;
No.2, 3 mm), peri choledochal lymph node (2.0 x 1.0 x 0.8 cm), and
right adrenal gland (5.82 grams, 6 x 3.7 x 1.5 cm), right lobe
liver (2,680 grams, 27.5 x 19.5 x 12.5 cm), and cystic duct lymph
node (0.6 x 0.5 x 0.4 cm).

DIAGNOSIS:

Liver, right lobe, hepatectomy: Grade 3 (of 4) hepatocellular carcinoma, usual type, forming a dominant 16 x 15 x 13 cm mass with innumerable satellite nodules ranging in size from 0.5 cm to 6 cm. The tumor is located in the right lobe. The hepatic capsule is involved, but adjacent organs spared. The surgical margins are involved grossly. Extratumoral vascular invasion is identified, involving portal veins microscopically. The tumor is partially encapsulated, infiltration of parenchyma being of infiltrating type.

A single separately submitted periportal lymph node is negative for tumor. Information regarding the uninvolved hepatic parenchyma will be reported in an addendum.

Adrenal gland, right, excision: Metastatic grade 2 (of 4) hepatocellular carcinoma forming multiple (2) separate masses (1.4 x 1.3 x 1.1 cm and 0.4 x 0.3 x 0.3 cm).

Gallbladder, cholecystectomy: Chronic cholecystitis with cholesterosis. Negative for tumor.

Peritoneal, No.1 and No.2, biopsies: Negative for tumor.

Lymph nodes, cystic duct and pericholedochal, excision: A single cystic duct lymph node and a single pericholedochal lymph node are negative for tumor.

ADDENDUM:

The non-neoplastic liver is non-cirrhotic and shows changes that are likely related to adjacent mass effect. No ground-glass hepatocytes are seen.

ICDPA Discrepancy		

[page 2 of 4]
ICD-0-3

Carcinoma, hepatocellular, Nos 8170/3

Site: liver c22.0 1/24/11
ju

Patient Key:
Surgical date: -

[TISSUE DESCRIPTION:

16 A1 A2 B1 C1 D1 E1 E2 F1 F2 F3 F4 F5 F6 F7
Gallbladder (8.0 x 3.5 x 2.8 cm), peritoneal biopsies (No.1, 3 mm;
No.2, 3 mm), peri choledochal lymph node (2.0 x 1.0 x 0.8 cm), and
right adrenal gland (5.82 grams, 6 x 3.7 x 1.5 cm), right lobe
liver (2,680 grams, 27.5 x 19.5 x 12.5 cm), and cystic duct lymph
node (0.6 x 0.5 x 0.4 cm).

DIAGNOSIS:

Liver, right lobe, hepatectomy: Grade 3 (of 4) hepatocellular
carcinoma, usual type, forming a dominant 16 x 15 x 13 cm mass with
innumerable satellite nodules ranging in size from 0.5 cm to 6 cm.
The tumor is located in the right lobe. The hepatic capsule is
involved, but adjacent organs spared. The surgical margins are
involved grossly. Extratumoral vascular invasion is identified,
involving portal veins microscopically. The tumor is partially
encapsulated, infiltration of parenchyma being of infiltrating type.

A single separately submitted periportal lymph node is negative for
tumor. Information regarding the uninvolved hepatic parenchyma will
be reported in an addendum.

Adrenal gland, right, excision: Metastatic grade 2 (of 4)
hepatocellular carcinoma forming multiple (2) separate masses (1.4 x
1.3 x 1.1 cm and 0.4 x 0.3 x 0.3 cm).

Gallbladder, cholecystectomy: Chronic cholecystitis with
cholesterolosis. Negative for tumor.

Peritoneal, No.1 and No.2, biopsies: Negative for tumor.

✓ Lymph nodes, cystic duct and pericholedochal, excision: A single
cystic duct lymph node and a single pericholedochal lymph node are
negative for tumor.

ADDENDUM:

The non-neoplastic liver is non-cirrhotic and shows changes that are
likely related to adjacent mass effect. No ground-glass hepatocytes
are seen.

[page 3 of 4]
Liver • Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: Resection

Patient name: *(to be de-identified)* **Patient key:**

~~Surgical pathology number:~~
Surgery Date :

MACROSCOPIC

Specimen Type

- ☒ Right lobectomy
☐ Extended right lobectomy
☐ Medial segmentectomy
☐ Left lateral segmentectomy
☐ Total left lobectomy
☐ Explanted liver
☐ Other (specify): _____
☐ Not specified

Focality

- ☒ Solitary (specify location): _____
☒ Multiple (specify location): right lobe (0.5x0.0cm)

Tumor Size

Greatest dimension: 1.6 cm

*Additional dimensions: 5.0 x 1.3 cm

☐ Cannot be determined (see Comment)

MICROSCOPIC

Histologic Type

- ☒ Hepatocellular carcinoma
☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
☐ Combined hepatocellular and cholangiocarcinoma
☐ Cholangiocarcinoma, intrahepatic
☐ Bile duct cystadenocarcinoma
☐ Undifferentiated carcinoma
☐ Other (specify): _____
☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
☐ GX: Cannot be assessed
☐ GI: Well differentiated
☒ GII: Moderately differentiated
☒ GIII: Poorly differentiated
☐ GIV: Undifferentiated/anaplastic
☐ Other (specify): _____

[page 4 of 4]
* Other (specify): _____

Source: NCI Genomic Data Commons file 9e68138b-7b05-4098-a8ac-c52d0cce8654 (TCGA-DD-A119.F8B8C948-933A-4B28-A0D1-98166C9B16EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).